Somatic mutation profile of tumor specimen 0DX0R2 from CCDI case PBCPWU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.8 years (1,037 days).
Specimen 0DX0R2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68d91f21-b0a0-448d-91db-51eebaff258f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe2cfecf-d68d-4035-a697-19ea74ccd35c

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1, Missense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NKAPD1 | c.398G>A p.G133E (on ENST00000280352 / NM_001082970.2; = p.G134E on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/518 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs981629227; called by muse, varscan2
- TULP2 | c.1447+1G>T p.X483_splice | Splice Site (SNP) | VAF 90/272 reads (33%) | catalogued as rs748715040; called by muse, varscan2
- ALS2CL | c.1104C>T p.H368= | Silent (SNP) | VAF 31/224 reads (14%) | catalogued as rs142517358; called by muse, varscan2
- TTC34 | c.2457G>A p.P819= | Silent (SNP) | VAF 90/217 reads (41%) | catalogued as rs896323500; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, varscan2
- NR1H3 | c.*50G>C | 3'UTR (SNP) | VAF 78/176 reads (44%) | called by muse, varscan2
